TARGET case TARGET-30-PALJVX — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6c54e998-a3b5-57a6-b50c-5cd88ac45879

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,836 days (7.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.1; Tissue or organ of origin: Medulla of adrenal gland; Classification of tumor: primary; Age at diagnosis: 4.5 years (1,635 days); Year of diagnosis: 2002; Days to last follow up: 2,836 days (7.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 50; Percent tumor nuclei: 50.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0621.
   Treatment given: Protocol identifier: A3973.
   Treatment given: Protocol identifier: ANBL0032.

Follow-up (3 entries)
- Days to follow up: 1,493 days (4.1 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 1,493 days (4.1 years); First event: Relapse.
- Days to follow up: 1,493 days (4.1 years); Progression or recurrence anatomic site: Bone marrow.
- Days to follow up: 2,836 days (7.8 years); Year of follow up: 2009.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PALJVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALJVX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2836
- Protocol: ANBL00B1, A3973, ANBL0032, ANBL0621
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.12
- Histology: Unfavorable
- MKI: Low
- Percent Tumor v/s Stroma: 75/25
- Site of Relapse: Primary Site; Bone Marrow; Other, specify: Multiple bone sites
